Somatic mutation profile of tumor specimen MP2PRT-PAVJJG-TBP1-A (aliquot MP2PRT-PAVJJG-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVJJG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,693 days).
Specimen MP2PRT-PAVJJG-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2337d001-7e96-421b-b9e5-53e9c1d1a309.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJJG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJJG-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c85d2c5-4601-4a20-8181-767c33c5223b

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs534252499; called by muse, mutect2, varscan2
- ATP4A | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404726499; called by muse, varscan2
- BRINP3 | c.182C>A p.T61K | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV66544124; called by muse, mutect2, varscan2
- DCANP1 | c.419C>G p.P140R | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.045); catalogued as rs750028665; called by muse, mutect2, varscan2
- DMRTB1 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 110/606 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1419190423; called by muse, mutect2, varscan2
- DQX1 | c.1565C>T p.T522M | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as rs201543859; called by muse, mutect2, varscan2
- FAT4 | c.5012G>A p.R1671H | Missense Mutation (SNP) | VAF 88/437 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs375605783; called by muse, mutect2, varscan2
- LAMA5 | c.1282+1G>A p.X428_splice | Splice Site (SNP) | VAF 61/287 reads (21%) | catalogued as rs1168208619; called by muse, mutect2, varscan2
- PHF24 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 89/347 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs199743237; called by muse, mutect2, varscan2
- RTL1 | c.3241C>T p.R1081* | Nonsense Mutation (SNP) | VAF 139/610 reads (23%) | catalogued as rs546784730, COSV66016599; called by muse, mutect2, varscan2
- USP36 | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 102/495 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61750004; called by muse, mutect2, varscan2
- ZP4 | c.1390+1G>A p.X464_splice | Splice Site (SNP) | VAF 61/246 reads (25%) | catalogued as rs760401172; called by muse, mutect2, varscan2
- DGCR8 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- IGFLR1 | c.288_326delinsGG p.V97Gfs*63 | Frame Shift Del (DEL) | VAF 77/452 reads (17%) | called by pindel, varscan2*
- TRIM63 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- C1QTNF9 | c.102C>T p.P34= | Silent (SNP) | VAF 18/502 reads (4%) | catalogued as rs1332039111; called by muse, mutect2
- IL20RA | c.114T>G p.P38= | Silent (SNP) | VAF 14/398 reads (4%) | called by muse, mutect2
- MRC2 | c.2217C>T p.H739= | Silent (SNP) | VAF 68/309 reads (22%) | catalogued as rs376529525; called by muse, mutect2, varscan2
- PACS2 | c.951G>A p.P317= | Silent (SNP) | VAF 18/492 reads (4%) | catalogued as rs587691097, COSV57658597; called by muse, mutect2
- PLCXD3 | c.846G>A p.T282= | Silent (SNP) | VAF 87/298 reads (29%) | catalogued as rs769179742, COSV60605850; called by muse, mutect2, varscan2
- PTPRB | c.345C>T p.G115= | Silent (SNP) | VAF 93/366 reads (25%) | called by muse, mutect2, varscan2
- ZFP92 | c.1170C>T p.T390= | Silent (SNP) | VAF 147/883 reads (17%) | catalogued as rs1249751801; called by muse, mutect2, varscan2
